Gene-level copy-number profile of tumor specimen TCGA-IN-A6RS-01A from TCGA case TCGA-IN-A6RS, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cardia, NOS; AJCC pathologic stage: Stage IA; Tumor grade: G2; Age at diagnosis: 76.1 years (27,808 days).
Specimen TCGA-IN-A6RS-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.f286c21f-7b9b-4c33-bdc8-46ae91bea39b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-IN-A6RS-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/925eb2eb-a425-47bb-aa22-ae2c7c08095a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 12; copy number 1: 10,118; copy number 2: 35,970; copy number 3: 10,890; copy number 4: 1,426; copy number 5: 514; copy number 6: 432; copy number 7: 112; copy number 8: 33; copy number 10: 1; copy number 13: 154; copy number 14: 153.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-IN-A6RS-01A-12D-A34T-01): tumor purity 0.48, ploidy 2.18, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 12 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:175,632,934–176,277,571, 8 genes (within-gene range 0–1): GPM6A, AC097537.1, AC110794.1, MARK2P4, WDR17, AC093605.1, SPATA4, ASB5.
- chr12:128,944,274–129,016,663, 2 genes: AC069262.1, NLRP9P1.
- chr12:129,109,629–129,170,238, 2 genes: TMEM132D-AS1, AC107033.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,399 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:40,391,591–44,830,188, 154 genes, copy number 13 (within-gene range 1–13) (broad region; genes not listed).
- chr6:44,898,711–44,899,295, 1 gene, copy number 10: NUDT19P4.
- chr7:68,020,235–69,597,493, 18 genes, copy number 6: AC092637.1, AC006013.1, MTCO1P57, AC093655.1, AC093655.2, MTND4P3, AC004910.1, RNA5SP231, AC104688.1, RNU6-832P, AC069280.2, AC092100.1, AC069280.1, MTCO2P25, MTCO1P25, RNU6-229P, Y_RNA, CT66.
- chr8:150,584–23,854,806, 555 genes, copy number 5–7 (within-gene range 5–12) (broad region; genes not listed).
- chr8:43,672,823–43,674,591, 2 genes, copy number 5: AC139365.2, AC139365.1.
- chr9:132,670,035–133,659,329, 45 genes, copy number 6: GTF3C4, AK8, AL445645.1, SPACA9, TSC1, GFI1B, MIR548AW, AL593851.1, RNU7-21P, EEF1A1P5, GTF3C5, MIR6877, CEL, CELP, RALGDS, AL162417.1, GBGT1, OBP2B, LCN1P1, ABO, Y_RNA, LCN1P2, SURF6, Y_RNA, MED22, AL772161.1, RPL7A, SNORD24, SNORD36B, SNORD36A, SNORD36C, SURF1, SURF2, SURF4, STKLD1, REXO4, ADAMTS13, CACFD1, SLC2A6, MYMK, ADAMTSL2, FAM163B, AC002101.1, DBH, DBH-AS1.
- chr12:89,519,408–93,215,679, 60 genes, copy number 6–8 (within-gene range 1–8): POC1B-GALNT4, GALNT4, POC1B-AS1, AC025034.2, AC025034.1, ATP2B1, ATP2B1-AS1, AC009522.1, RNA5SP365, MRPL2P1, RNU6-148P, BRWD1P2, LINC02399, AC126178.1, LINC02392, LINC02822, AC084365.1, AC112481.2, AC112481.1, CCER1, LINC00615, EPYC, KERA, LUM, DCN, AC007115.1, LINC02823, AC090016.1, AC126175.1, AC126175.2, AC025254.1, AC090049.2, LINC02404, AC090049.1, LINC01619, AC123512.1, AC025164.2, BTG1, AC025164.1, RPL21P106, Y_RNA, LINC02391, CLLU1-AS1, CLLU1, AC063949.2, LINC02397, AC063949.1, PLEKHG7, EEA1, AC026111.1, HNRNPA1P50, RNU6-1329P, LINC02413, AC138123.1, Y_RNA, AC021646.1, RPL41P5, AC138123.2, NACAP8, LINC02412.
- chr12:95,467,397–97,761,859, 54 genes, copy number 5: AC018475.1, METAP2, USP44, PGAM1P5, Y_RNA, NTN4, AC090001.1, RNU6-247P, LINC02410, SNRPF, CCDC38, AC090001.2, AMDHD1, HAL, AC007298.2, LTA4H, AC007298.1, YPEL5P3, RN7SL88P, LINC02452, ELK3, AC008149.1, AC008149.2, CDK17, RNU4-24P, AC125612.1, AC007513.1, RN7SKP11, CFAP54, EEF1A1P33, NEDD1, Y_RNA, AC007656.2, AC007656.1, AC007656.3, AC007656.4, LINC02409, RMST, MIR1251, AC007351.2, AC007351.3, AC007351.4, AC007351.1, AC018659.4, AC018659.3, AC018659.1, AC018659.7, AC018659.5, AC018659.8, MIR135A2, AC018659.6, AC018659.2, PAFAH1B2P2, RNU6-36P.
- chr12:98,726,457–99,984,654, 1 gene, copy number 7 (within-gene range 4–7): ANKS1B.
- chr12:99,647,753–104,762,014, 106 genes, copy number 7 (broad region; genes not listed).
- chr12:105,173,297–114,241,770, 210 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr16:18,781,295–20,073,890, 40 genes, copy number 6: RPS15A, AC138811.2, ARL6IP1, AC138811.1, SMG1, AC092287.1, TMC7, RNU6-1340P, AC099518.4, AC099518.2, COQ7, AC099518.1, AC099518.6, ITPRIPL2, AC099518.3, AC099518.5, SYT17, AC010494.1, CLEC19A, AC130456.1, LINC02858, AC130456.2, AC130456.7, TMC5, AC130456.4, AC130456.3, RNU4-46P, AC130456.5, GDE1, AC130456.6, CCP110, VPS35L, AC002550.2, KNOP1, AC002550.1, IQCK, AC027130.1, LARP7P2, GPRC5B, GPR139.
- chr17:39,461,486–41,812,604, 153 genes, copy number 14 (within-gene range 2–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 7,697. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
